MMRF case MMRF_2504 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bcc7d2bf-0093-4882-bd74-bdee0090fc2d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 32 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 32.4 years (11,848 days); ISS stage: II; Days to last known disease status: 633 days (1.7 years); Days to last follow up: 633 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 54 days; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 118 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 201 days; Days to treatment end: 201 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 633.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 13 (ECOG 1): M Protein 7.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 95.4 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 3.29 µg/mL; Hemoglobin 5.52 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 398 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.7 mmol/L; Albumin 31 g/L; Total Protein 15.6 g/dL; Glucose 4.68 mmol/L; C-Reactive Protein 14.9 mg/dL.
- Day 81: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Hemoglobin 8.68 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.06 mmol/L.
- Day 293: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.083 mg/dL; Hemoglobin 8.25 mmol/L; Leukocytes 2.89 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 4.57 mmol/L.
- Day 577: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin A 0.662 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 8.1 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 13: Weight: 60 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2504_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 13 days.
- Sample MMRF_2504_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 13 days.
